Gene-level copy-number profile of tumor specimen TCGA-CR-7380-01A from TCGA case TCGA-CR-7380, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 58.1 years (21,215 days).
Specimen TCGA-CR-7380-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.00962543-3cc3-4411-abfe-658fb721ba46.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,213 have no estimate.
https://portal.gdc.cancer.gov/files/0c7fe20e-e28d-431f-bdf8-75a96a2c8b41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 13,994; copy number 2: 38,594; copy number 3: 1,580; copy number 4: 1,147; copy number 5: 93.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-7380-01A-11D-2010-01): tumor purity 0.66, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:186,486,253–186,509,361, 2 genes: ZC3H15, DPRXP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 93 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:176,723,614–177,559,299, 27 genes, copy number 5 (within-gene range 3–5): AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B.
- chr11:69,371,463–71,670,297, 64 genes, copy number 5 (broad region; genes not listed).
- chr11:71,690,453–71,705,404, 2 genes, copy number 5: SNRPCP14, AP003498.1.

Autosomal genes at a single copy (total copy number 1): 13,994. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
